Somatic mutation profile of tumor specimen TCGA-DJ-A2QA-01A (aliquot TCGA-DJ-A2QA-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2QA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 56.9 years (20,784 days).
Specimen TCGA-DJ-A2QA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8c5c420-aae1-439f-b467-423da5c01add.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2QA-10A (Blood Derived Normal), aliquot TCGA-DJ-A2QA-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7af4cd9c-f155-417e-b6f6-d6e19a36b2a1

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ARHGEF2 | c.1681A>G p.T561A (on ENST00000361247 / NM_001162383.2; = p.T533A on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV58118345; called by muse, mutect2
- DNASE2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52257138; called by muse, mutect2, varscan2
- FRS3 | c.1403A>G p.N468S | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52487357; called by muse, mutect2
- ITGB3 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV71385377; called by muse, mutect2, varscan2
- KMT2C | c.9638C>T p.S3213L | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100079309, COSV51288409, COSV51482938; called by muse, mutect2, varscan2
- PDS5B | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.318); catalogued as COSV59736330; called by muse, mutect2, varscan2
- ELF4 | c.438G>T p.R146S | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2
- CRP | c.594C>T p.F198= | Silent (SNP) | VAF 34/146 reads (23%) | catalogued as COSV54812654, COSV54815019; called by muse, mutect2, varscan2
- RALB | c.582G>A p.K194= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV55605522; called by muse, mutect2, varscan2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 11/35 reads (31%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by muse, mutect2, varscan2
